Somatic mutation profile of tumor specimen 80873a0c-1f40-4d51-bab1-3f2071 (aliquot 80873a0c-1f40-4d51-bab1-3f2071_D6) from CPTAC case 17OV036, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary.
Specimen 80873a0c-1f40-4d51-bab1-3f2071: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4da6b841-8997-47be-b49e-8029b0b4f558.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen f0147adf-97a9-482c-af88-90da35 (Blood Derived Normal), aliquot f0147adf-97a9-482c-af88-90da35_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e72aaaa1-44b5-4dc3-8168-d36ef20f99e4

The open-access MAF lists 47 somatic variants for this specimen: 32 protein-altering or splice-affecting, 9 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 9, Intron 5, Frame Shift Del 2, RNA 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFAP1L2 | c.505G>A p.G169S | Missense Mutation (SNP) | VAF 49/395 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755311509; called by muse, mutect2, varscan2
- CERS6 | c.679A>G p.M227V | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as COSV59830920; called by muse, mutect2, varscan2
- CFAP65 | c.2066C>T p.T689M | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.803); catalogued as rs769586505, COSV58559280; called by muse, mutect2, varscan2
- CLTC | c.1085A>G p.E362G | Missense Mutation (SNP) | VAF 107/436 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.423); catalogued as rs1280430512; called by muse, mutect2, varscan2
- DOCK6 | c.5740C>T p.R1914W | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.892); catalogued as rs776932453, COSV53910799; called by muse, mutect2, varscan2
- HK1 | c.2725G>A p.V909M | Missense Mutation (SNP) | VAF 76/343 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.404); catalogued as rs1280568609; called by muse, varscan2
- IGSF3 | c.1748G>A p.R583Q (on ENST00000369486 / NM_001007237.3; = p.R603Q on NM_001542.4) | Missense Mutation (SNP) | VAF 90/398 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.974); catalogued as rs770971514; called by muse, mutect2, varscan2
- INSM1 | c.1190G>A p.G397D | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV59604445; called by muse, mutect2, varscan2
- ITPR1 | c.1450G>A p.V484I (on ENST00000354582; = p.V469I on NM_002222.7) | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.535); catalogued as rs752031193; called by muse, mutect2, varscan2
- LRRC14 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1408535311; called by muse, mutect2, varscan2
- RYR3 | c.10717G>A p.D3573N (on ENST00000389232; = p.D3574N on NM_001036.6) | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs370636001; called by muse, mutect2, varscan2
- SALL3 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.267); catalogued as rs1178185252; called by muse, mutect2, varscan2
- SMARCAL1 | c.2218G>A p.A740T | Missense Mutation (SNP) | VAF 73/268 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as rs1249862879; called by muse, mutect2, varscan2
- TMEM102 | c.1502C>A p.A501E | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.978); catalogued as COSV53439593; called by muse, mutect2
- TP53 | c.997del p.R333Vfs*12 | Frame Shift Del (DEL) | VAF 18/74 reads (24%) | catalogued as CM137619, COSV52774724; called by mutect2, pindel, varscan2
- TTN | c.27226G>A p.G9076R (on ENST00000591111; = p.G8149R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/134 reads (19%) | PolyPhen benign (0.158); catalogued as rs745513677; called by muse, mutect2, varscan2
- CAPN15 | c.2434C>A p.P812T | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- CELSR1 | c.5761G>T p.A1921S | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.01); called by muse, mutect2
- DNAJC25 | c.773dup p.Y259Ifs*11 | Frame Shift Ins (INS) | VAF 96/420 reads (23%) | called by mutect2, pindel, varscan2
- EHHADH | c.1663A>C p.N555H | Missense Mutation (SNP) | VAF 174/393 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- JADE1 | c.103T>C p.S35P | Missense Mutation (SNP) | VAF 75/227 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- LIN9 | c.602A>G p.N201S (on ENST00000366808 / NM_001270410.2; = p.N146S on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.514); called by muse, mutect2
- LPIN2 | c.878C>G p.S293* | Nonsense Mutation (SNP) | VAF 81/415 reads (20%) | called by muse, mutect2, varscan2
- MAB21L2 | c.33G>C p.Q11H | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MRPL3 | c.662G>C p.R221T | Missense Mutation (SNP) | VAF 55/340 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NASP | c.1312G>A p.G438R | Missense Mutation (SNP) | VAF 51/187 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- NRXN2 | c.1592T>A p.L531H | Missense Mutation (SNP) | VAF 71/236 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR6B3 | c.799T>A p.S267T | Missense Mutation (SNP) | VAF 18/395 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.042); called by muse, mutect2
- PRC1 | c.893G>T p.R298L | Missense Mutation (SNP) | VAF 36/205 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPN1 | c.209G>C p.S70T | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- TTC4 | c.284A>G p.Y95C | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TUBD1 | c.604del p.L202Ffs*15 | Frame Shift Del (DEL) | VAF 55/273 reads (20%) | called by mutect2, pindel, varscan2
- ACHE | c.369G>A p.L123= | Silent (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
- CD300E | c.591G>A p.R197= | Silent (SNP) | VAF 30/84 reads (36%) | called by muse, mutect2, varscan2
- CLIC6 | c.1293C>A p.R431= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as rs1023179553; called by muse, mutect2
- FCGBP | c.2433C>T p.G811= | Silent (SNP) | VAF 40/188 reads (21%) | called by muse, mutect2, varscan2
- LRP1 | c.1119G>A p.T373= | Silent (SNP) | VAF 69/311 reads (22%) | catalogued as rs1406975254, COSV54518912; called by muse, mutect2, varscan2
- NRP2 | c.2610C>T p.I870= (on ENST00000360409 / NM_201266.2; = p.I865= on NM_003872.3) | Silent (SNP) | VAF 78/301 reads (26%) | catalogued as rs757060576, COSV63369831; called by muse, mutect2, varscan2
- RASAL3 | c.1809G>A p.L603= | Silent (SNP) | VAF 29/119 reads (24%) | catalogued as rs1480845264; called by muse, mutect2
- SLC25A18 | c.129C>A p.A43= | Silent (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- WNT7A | c.480C>T p.I160= | Silent (SNP) | VAF 104/391 reads (27%) | catalogued as rs774318482; called by muse, mutect2, varscan2
- GABRG3 | c.271-55229G>T | Intron (SNP) | VAF 30/166 reads (18%) | called by muse, mutect2, varscan2
- LINC02877 | n.544C>T | RNA (SNP) | VAF 32/140 reads (23%) | catalogued as rs1305680600; called by muse, mutect2, varscan2
- PHLDB1 | c.2380-371C>T | Intron (SNP) | VAF 22/70 reads (31%) | called by muse, mutect2, varscan2
- SLC25A42 | c.213+15C>A | Intron (SNP) | VAF 28/108 reads (26%) | called by muse, mutect2, varscan2
- SPACA7 | c.94+2241G>A | Intron (SNP) | VAF 37/169 reads (22%) | catalogued as rs1264636567; called by muse, mutect2, varscan2
- TM6SF1 | c.92+32G>C | Intron (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2, varscan2
